Gene-level copy-number profile of tumor specimen C3L-05849-02 from CPTAC case C3L-05849, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 64.3 years (23,490 days).
Specimen C3L-05849-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e0bdf7fd-8f09-4e2b-92f4-d0805763bb29.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05849-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/de8844fe-a52f-434c-b06c-4dbdd5be4bc4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9; copy number 2: 58,208; copy number 3: 87; copy number 4: 16; copy number 5: 63; copy number 6: 23.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 86 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:46,677,080–47,164,385, 11 genes, copy number 5 (within-gene range 3–5): ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, C11orf49, AC103792.1.
- chr11:47,331,406–47,565,569, 9 genes, copy number 5 (within-gene range 3–5): MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN, CELF1, AC090559.2.
- chr19:21,020,634–21,678,221, 32 genes, copy number 5: ZNF430, AC008739.3, VN1R80P, ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10, VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1, ZNF493, AC010615.4, AC010615.2, LINC00664, ZNF429, BNIP3P26, AC123912.1, AC123912.4, AC123912.2, AC123912.6, AC123912.5, AC123912.3, MTDHP3.
- chr19:22,017,898–22,245,347, 11 genes, copy number 5: AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.1.
- chr19:29,205,320–30,038,181, 23 genes, copy number 6: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
